Somatic mutation profile of tumor specimen ALCH-AEUQ-TTP1-A (aliquot ALCH-AEUQ-TTP1-A-1-0-D-A657-36) from ALCHEMIST case ALCH-AEUQ, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 68.4 years (24,984 days).
Specimen ALCH-AEUQ-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 84eb04d4-a2ae-49dd-a630-916fb6955661.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-AEUQ-NB1-A (Blood Derived Normal), aliquot ALCH-AEUQ-NB1-A-2-0-D-A658-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6fd4fe95-7d99-4651-ab84-d4cd2db651db

The open-access MAF lists 52 somatic variants for this specimen: 38 protein-altering or splice-affecting, 8 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 30, Silent 8, Nonsense Mutation 5, RNA 3, 3'UTR 2, Splice Site 1, Frame Shift Ins 1, Splice Region 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CDK4 | c.64A>C p.K22Q | Missense Mutation (SNP) | VAF 95/584 reads (16%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1555201381, COSV56983663; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- EGFR | c.2573T>G p.L858R | Missense Mutation (SNP) | VAF 119/1616 reads (7%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121434568, COSV51765161, COSV51854030; ClinVar: likely pathogenic / drug response / pathogenic; called by muse, mutect2
- TP53 | c.517G>A p.V173M | Missense Mutation (SNP) | VAF 52/303 reads (17%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.952); catalogued as rs876660754, CM070299, COSV52676535, COSV52677795, COSV52695723, COSV52823354; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ARID1A | c.6619C>T p.Q2207* | Nonsense Mutation (SNP) | VAF 32/177 reads (18%) | catalogued as COSV61374784; called by muse, mutect2, varscan2
- CARTPT | c.310C>T p.R104* | Nonsense Mutation (SNP) | VAF 84/533 reads (16%) | catalogued as rs78011348; called by muse, mutect2, varscan2
- IL9R | c.759C>A p.C253* | Nonsense Mutation (SNP) | VAF 54/341 reads (16%) | catalogued as rs758627215, COSV99730288; called by muse, mutect2, varscan2
- LUM | c.523G>C p.A175P | Missense Mutation (SNP) | VAF 35/175 reads (20%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.583); catalogued as COSV99898955; called by muse, mutect2, varscan2
- MMP1 | c.169A>G p.S57G | Missense Mutation (SNP) | VAF 57/455 reads (13%) | SIFT tolerated (0.25); PolyPhen benign (0.03); catalogued as rs1263897390; called by muse, mutect2, varscan2
- MYRIP | c.391C>T p.R131C | Missense Mutation (SNP) | VAF 20/153 reads (13%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.997); catalogued as rs755354103; called by muse, mutect2, varscan2
- PCDH17 | c.386C>T p.A129V | Missense Mutation (SNP) | VAF 22/807 reads (3%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.594); catalogued as COSV64980270; called by muse, mutect2
- PYGM | c.704G>A p.R235H | Missense Mutation (SNP) | VAF 37/426 reads (9%) | SIFT tolerated (0.1); PolyPhen benign (0.05); catalogued as rs371247639; called by muse, mutect2
- SSBP3 | c.623G>A p.G208D (on ENST00000371320 / NM_145716.4; = p.G188D on NM_018070.5) | Missense Mutation (SNP) | VAF 27/222 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.818); catalogued as rs1377073049; called by muse, mutect2, varscan2
- TGIF2LX | c.530C>T p.S177L | Missense Mutation (SNP) | VAF 118/930 reads (13%) | SIFT tolerated (0.69); PolyPhen benign (0); catalogued as COSV52213203; called by muse, mutect2, varscan2
- TMEM182 | c.407G>T p.C136F | Missense Mutation (SNP) | VAF 28/302 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV68425396; called by muse, mutect2
- ZFP69 | c.680G>T p.G227V | Missense Mutation (SNP) | VAF 62/438 reads (14%) | SIFT tolerated (0.3); PolyPhen benign (0.001); catalogued as COSV65529494; called by muse, mutect2, varscan2
- ADGRV1 | c.16103T>C p.I5368T | Missense Mutation (SNP) | VAF 12/149 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.036); called by muse, mutect2
- AGAP5 | c.714C>G p.N238K | Missense Mutation (SNP) | VAF 32/898 reads (4%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.932); called by muse, mutect2
- AGMO | c.435C>A p.H145Q | Missense Mutation (SNP) | VAF 58/397 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ANKRD11 | c.2281T>C p.Y761H | Missense Mutation (SNP) | VAF 80/1081 reads (7%) | SIFT tolerated (0.79); PolyPhen benign (0.001); called by muse, mutect2
- ANKRD44 | c.2362A>G p.I788V | Missense Mutation (SNP) | VAF 41/285 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- BTN3A2 | c.983C>T p.S328F | Missense Mutation (SNP) | VAF 29/301 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.146); called by muse, mutect2
- CCDC168 | c.5230A>G p.K1744E | Missense Mutation (SNP) | VAF 24/235 reads (10%) | SIFT tolerated (0.3); PolyPhen benign (0.282); called by muse, varscan2
- COL11A1 | c.2556G>T p.K852N | Missense Mutation (SNP) | VAF 14/392 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.351); called by muse, mutect2
- DCHS1 | c.5752G>T p.D1918Y | Missense Mutation (SNP) | VAF 64/428 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DYSF | c.3442+1G>T p.X1148_splice | Splice Site (SNP) | VAF 88/634 reads (14%) | called by muse, mutect2, varscan2
- FOXL1 | c.725C>A p.S242Y | Missense Mutation (SNP) | VAF 36/139 reads (26%) | SIFT tolerated (0.58); PolyPhen benign (0.365); called by muse, mutect2, varscan2
- FRYL | c.6052G>T p.E2018* | Nonsense Mutation (SNP) | VAF 18/418 reads (4%) | called by muse, mutect2
- MED13 | c.1619C>T p.P540L | Missense Mutation (SNP) | VAF 27/110 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.057); called by muse, mutect2, varscan2
- NKAIN3 | c.110T>A p.I37N | Missense Mutation (SNP) | VAF 36/218 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- OR4E2 | c.596T>C p.I199T | Missense Mutation (SNP) | VAF 36/196 reads (18%) | SIFT tolerated (0.06); PolyPhen benign (0.046); called by muse, mutect2, varscan2
- PGAP1 | c.1768G>A p.V590I | Missense Mutation (SNP) | VAF 14/217 reads (6%) | SIFT tolerated (0.94); PolyPhen benign (0.005); called by muse, mutect2
- PON2 | c.145+3A>G | Splice Region (SNP) | VAF 22/508 reads (4%) | called by muse, mutect2
- PRKCSH | c.851C>T p.A284V | Missense Mutation (SNP) | VAF 49/361 reads (14%) | SIFT tolerated (0.66); PolyPhen benign (0.001); called by muse, varscan2
- QSOX1 | c.1140G>T p.E380D | Missense Mutation (SNP) | VAF 36/154 reads (23%) | SIFT tolerated (0.26); PolyPhen benign (0.103); called by muse, mutect2, varscan2
- SF3B1 | c.532G>C p.A178P | Missense Mutation (SNP) | VAF 23/187 reads (12%) | SIFT tolerated (0.18); PolyPhen benign (0.048); called by muse, mutect2, varscan2
- TAF1 | c.3691C>T p.P1231S (on ENST00000373790 / NM_138923.4; = p.P1252S on NM_004606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 22/201 reads (11%) | SIFT tolerated (0.13); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- UBE2QL1 | c.81G>A p.W27* | Nonsense Mutation (SNP) | VAF 43/263 reads (16%) | called by muse, mutect2, varscan2
- XIRP2 | c.4417dup p.H1473Pfs*3 (on ENST00000628543; = p.H1648Pfs*3 on NM_152381.6) | Frame Shift Ins (INS) | VAF 21/207 reads (10%) | called by mutect2, pindel, varscan2
- AFAP1L1 | c.1581G>A p.V527= | Silent (SNP) | VAF 15/339 reads (4%) | called by muse, mutect2
- DOCK7 | c.5865G>A p.G1955= (on ENST00000635253 / NM_001367561.1; = p.G1924= on NM_033407.3) | Silent (SNP) | VAF 34/642 reads (5%) | called by muse, mutect2
- FRMPD3 | c.3153C>T p.T1051= | Silent (SNP) | VAF 66/500 reads (13%) | catalogued as rs1277951036; called by muse, mutect2, varscan2
- GRHPR | c.525C>T p.F175= | Silent (SNP) | VAF 56/488 reads (11%) | catalogued as rs749885934, COSV58945798; called by muse, mutect2, varscan2
- HORMAD1 | c.1095T>C p.S365= | Silent (SNP) | VAF 35/319 reads (11%) | called by muse, mutect2, varscan2
- HRNR | c.636C>T p.S212= | Silent (SNP) | VAF 32/388 reads (8%) | catalogued as rs201296154, COSV64257258; called by muse, mutect2
- ILKAP | c.540A>T p.V180= | Silent (SNP) | VAF 40/325 reads (12%) | called by muse, mutect2, varscan2
- TKFC | c.873C>T p.R291= | Silent (SNP) | VAF 25/193 reads (13%) | catalogued as rs202066904; called by muse, varscan2
- LINC01193 | n.879A>G | RNA (SNP) | VAF 52/578 reads (9%) | called by muse, mutect2
- OR5P1P | n.279G>T | RNA (SNP) | VAF 20/243 reads (8%) | called by muse, mutect2
- PDE6G | c.*206G>T | 3'UTR (SNP) | VAF 8/208 reads (4%) | called by muse, mutect2
- STAG3L4 | n.738G>T | RNA (SNP) | VAF 16/172 reads (9%) | called by muse, mutect2
- SYT14 | c.*95T>C | 3'UTR (SNP) | VAF 108/825 reads (13%) | catalogued as rs1481633492; called by muse, mutect2, varscan2
- TUBB8 | c.-4G>A | 5'UTR (SNP) | VAF 7/96 reads (7%) | catalogued as rs1554739070; called by muse, mutect2
